Somatic mutation profile of tumor specimen TARGET-20-PATCYP-03A (aliquot TARGET-20-PATCYP-03A-01D) from TARGET case TARGET-20-PATCYP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.0 years (6,206 days).
Specimen TARGET-20-PATCYP-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38a587c2-3990-4a14-a941-291e20e6b067.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATCYP-14A (Bone Marrow Normal), aliquot TARGET-20-PATCYP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d7680fb-ed31-404b-94bc-b78d5c55e090

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/164 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.431); catalogued as CM156572, COSV60069719, COSV60069855, COSV60086929; called by muse, mutect2, varscan2
- KIT | c.1255_1257del p.D419del | In Frame Del (DEL) | VAF 60/164 reads (37%) | called by mutect2, pindel, varscan2
- LAMA1 | c.2303A>G p.H768R | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2
- PHF6 | c.908_912del p.Y303Lfs*8 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- TET2 | c.4679dup p.Y1560* | Nonsense Mutation (INS) | VAF 22/214 reads (10%) | called by mutect2, varscan2
